Somatic mutation profile of tumor specimen TCGA-60-2724-01A (aliquot TCGA-60-2724-01A-01W-0877-08) from TCGA case TCGA-60-2724, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.8 years (17,462 days).
Specimen TCGA-60-2724-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0159c09-2bd4-464d-a836-bd251ce9d89d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2724-11A (Solid Tissue Normal), aliquot TCGA-60-2724-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/985cd247-5290-4c87-92e0-b3715e909388

The open-access MAF lists 349 somatic variants for this specimen: 270 protein-altering or splice-affecting, 75 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 75, Nonsense Mutation 11, Splice Site 11, Frame Shift Ins 9, Frame Shift Del 5, Intron 3, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs879254517, CM002339, CM112162, COSV52943297; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 111/545 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.4592C>T p.S1531F | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64673614; called by muse, mutect2, varscan2
- ACSBG1 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51906088; called by muse, mutect2, varscan2
- ACTN2 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100856888, COSV63975014; called by muse, mutect2, varscan2
- ADAMTS10 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs1373094715; called by muse, mutect2, varscan2
- ADAMTS20 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67138812; called by muse, mutect2, varscan2
- AFDN | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs144621028; called by muse, mutect2, varscan2
- AFG3L2 | c.1729G>T p.G577C | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52314538; called by muse, mutect2, varscan2
- AICDA | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.189); catalogued as COSV57563767; called by muse, mutect2
- AL031777.2 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV61911932; called by muse, mutect2, varscan2
- ANGPTL6 | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53462325, COSV53463865; called by muse, mutect2, varscan2
- ANKIB1 | c.3049G>C p.V1017L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV56061555; called by muse, mutect2, varscan2
- ANKS4B | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61139256; called by muse, mutect2, varscan2
- ARHGAP11A | c.2035A>T p.T679S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55706363; called by muse, mutect2, varscan2
- ASPM | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1382867738, COSV54129445; called by muse, mutect2
- ATP6V1H | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 85/409 reads (21%) | catalogued as COSV62218316; called by muse, mutect2, varscan2
- B3GALT2 | c.677A>C p.N226T | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464056; called by muse, mutect2, varscan2
- BANK1 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV59842894; called by muse, mutect2, varscan2
- BCHE | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52256967; called by muse, mutect2, varscan2
- BIRC6 | c.9523A>T p.T3175S | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as rs201464207, COSV70199355; called by muse, mutect2, varscan2
- BLK | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs769734763, COSV52052205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB2 | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 122/463 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV50064776; called by muse, mutect2, varscan2
- BVES | c.451A>T p.M151L | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV58947941; called by muse, mutect2, varscan2
- C12orf40 | c.1639dup p.I547Nfs*6 | Frame Shift Ins (INS) | VAF 20/113 reads (18%) | catalogued as rs1409310027; called by mutect2, pindel, varscan2
- C3orf62 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55537136; called by muse, mutect2, varscan2
- CCDC39 | c.2537T>C p.I846T | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs959862071, COSV56480131; called by muse, mutect2
- CDH8 | c.1772C>A p.T591N | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54867838; called by muse, mutect2, varscan2
- CEP152 | c.1855G>T p.D619Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57859126; called by muse, mutect2, varscan2
- CEP192 | c.6965G>C p.S2322T | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV58064424; called by mutect2, varscan2
- CEP350 | c.8374G>C p.D2792H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV62602638; called by muse, mutect2, varscan2
- CFHR4 | c.126C>A p.Y42* (on ENST00000367416 / NM_001201551.2; = p.Y43* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 35/212 reads (17%) | catalogued as COSV52228764; called by muse, mutect2, varscan2
- CHD3 | c.1933G>T p.G645W | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875087; called by muse, mutect2, varscan2
- CHRNB2 | c.914T>C p.M305T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63808207; called by muse, mutect2, varscan2
- CILK1 | c.1520G>A p.S507N (on ENST00000350082 / NM_001375397.1; = p.S500N on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV63154208; called by muse, mutect2, varscan2
- CNGB3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 160/426 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60685142; called by muse, mutect2, varscan2
- CNR2 | c.404T>A p.L135Q | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65693005; called by muse, mutect2, varscan2
- CNTNAP2 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs764239461, COSV62180984, COSV62182718, COSV62237984; called by muse, mutect2, varscan2
- COL1A1 | c.4376G>T p.G1459V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV56804984; called by muse, mutect2, varscan2
- COL6A3 | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55089645; called by muse, mutect2, varscan2
- CORO1C | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54595974; called by muse, mutect2, varscan2
- CRACD | c.235A>T p.M79L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV51721265; called by muse, mutect2, varscan2
- CSF2RB | c.1745A>T p.K582I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs771023441, COSV53257869; called by muse, mutect2, varscan2
- CTIF | c.1244G>C p.R415P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); catalogued as COSV56483906, COSV56485004; called by muse, mutect2, varscan2
- CWC15 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 125/638 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54411632; called by muse, mutect2, varscan2
- CYTH2 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57309352; called by muse, mutect2, varscan2
- DCPS | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55010935; called by muse, mutect2, varscan2
- DDX59 | c.214G>C p.V72L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.026); catalogued as COSV58752008; called by muse, mutect2, varscan2
- DENND4A | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71265864; called by muse, mutect2, varscan2
- DLG1 | c.2129A>T p.E710V (on ENST00000419354 / NM_001290983.1; = p.E732V on NM_004087.2) | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV58383023; called by muse, mutect2, varscan2
- DNAH11 | c.3913C>G p.L1305V | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs1166589837, COSV60955970; called by muse, mutect2, varscan2
- DNTT | c.1321C>A p.R441S | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs200664457, COSV64523020, COSV64523636; called by muse, mutect2, varscan2
- DPP4 | c.2199+1G>A p.X733_splice | Splice Site (SNP) | VAF 23/115 reads (20%) | catalogued as COSV62106788; called by muse, mutect2, varscan2
- DPY19L2 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs762971724, COSV60543468; called by muse, mutect2, varscan2
- DSCAM | c.4726C>A p.L1576I | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.76); catalogued as COSV68026851; called by muse, mutect2, varscan2
- DYNC2I1 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.502); catalogued as rs746277876, COSV68104839; called by muse, mutect2
- EGFLAM | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 36/624 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.178); catalogued as COSV59302630, COSV59302907; called by muse, mutect2
- EGLN1 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 101/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64149203; called by muse, mutect2, varscan2
- ELOVL6 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV56429016; called by muse, mutect2, varscan2
- ENPEP | c.988T>A p.F330I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as COSV54451196; called by muse, mutect2, varscan2
- ENPP3 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62954239; called by muse, mutect2, varscan2
- ERC1 | c.2029G>A p.D677N (on ENST00000360905 / NM_178040.4; = p.D649N on NM_178039.4) | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV61695008; called by muse, mutect2, varscan2
- ERICH3 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV58606824; called by muse, mutect2, varscan2
- EVL | c.1003C>G p.P335A (on ENST00000402714 / NM_001330221.2; = p.P337A on NM_016337.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs750723779, COSV67375356, COSV67376696; called by muse, mutect2, varscan2
- F13B | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV66373892; called by muse, mutect2, varscan2
- F5 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158801095, COSV63124014; called by muse, mutect2, varscan2
- FAT1 | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as COSV71673965; called by muse, mutect2, varscan2
- FAT4 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101272510, COSV67886858; called by muse, mutect2, varscan2
- FBXL5 | c.1301A>G p.K434R | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV58011340; called by muse, mutect2, varscan2
- FBXO31 | c.341-2A>C p.X114_splice | Splice Site (SNP) | VAF 23/74 reads (31%) | catalogued as COSV61148921; called by muse, mutect2, varscan2
- FCRL1 | c.662T>A p.V221E | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV63825231; called by muse, mutect2, varscan2
- FER1L6 | c.2134-1G>C p.X712_splice | Splice Site (SNP) | VAF 109/406 reads (27%) | catalogued as COSV67549942; called by muse, mutect2, varscan2
- FLG | c.3362T>C p.V1121A | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.07); catalogued as COSV64241938; called by muse, mutect2, varscan2
- FLT4 | c.1655C>A p.T552N | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56108403; called by muse, mutect2, varscan2
- GABRG3 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV61518492; called by muse, mutect2, varscan2
- GPR180 | c.1163A>T p.K388M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65385602; called by muse, mutect2, varscan2
- GPRC5C | c.1427C>G p.S476C (on ENST00000652232; = p.S431C on NM_018653.4) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.885); catalogued as rs1471262881, COSV61235121; called by muse, mutect2, varscan2
- GRM3 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 115/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64471902; called by muse, mutect2, varscan2
- GRM3 | c.2479C>G p.L827V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as COSV64471913; called by muse, mutect2, varscan2
- GRXCR1 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67671792; called by muse, varscan2
- HERC1 | c.9319C>G p.R3107G | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV71246711, COSV71247846; called by muse, mutect2, varscan2
- HFM1 | c.3271A>G p.T1091A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV54027443; called by muse, mutect2, varscan2
- HLA-DMA | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.458); catalogued as rs199940435, COSV66385718; called by muse, mutect2, varscan2
- HRNR | c.2119T>A p.S707T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.834); catalogued as COSV64258030; called by muse, mutect2, varscan2
- HRNR | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV64264230; called by mutect2, varscan2
- HTR7 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.723); catalogued as COSV53286694; called by muse, mutect2, varscan2
- IGKV6D-41 | c.209A>T p.Y70F | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.025); catalogued as rs1382437388; called by muse, mutect2, varscan2
- IL1A | c.321A>G p.E107= | Splice Region (SNP) | VAF 89/164 reads (54%) | catalogued as COSV54519584; called by muse, mutect2, varscan2
- IL37 | c.82+1G>A p.X28_splice | Splice Site (SNP) | VAF 17/67 reads (25%) | catalogued as COSV54491097; called by muse, mutect2, varscan2
- ITGA8 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 85/371 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV65229008; called by muse, mutect2, varscan2
- ITPR2 | c.2037G>T p.M679I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs777460753, COSV67269400; called by muse, mutect2, varscan2
- IYD | c.190T>A p.W64R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.204); catalogued as COSV57601204; called by muse, mutect2, varscan2
- KCNB2 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 129/446 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV73050299; called by muse, mutect2, varscan2
- KCNJ8 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53716411; called by muse, mutect2, varscan2
- KCNMB4 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50691455; called by muse, mutect2, varscan2
- KCTD8 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV63589273; called by muse, mutect2, varscan2
- KDM5C | c.1937A>T p.E646V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV64765035; called by muse, mutect2, varscan2
- KDM6A | c.2833-2A>G p.X945_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as COSV65040269; called by muse, mutect2, varscan2
- KEL | c.1410C>A p.D470E | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV62335007; called by muse, mutect2, varscan2
- KIF1B | c.988G>T p.A330S (on ENST00000377086 / NM_001365952.1; = p.A324S on NM_015074.3) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55808901; called by muse, mutect2, varscan2
- KLHL25 | c.1478A>G p.Q493R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV61995147; called by muse, mutect2, varscan2
- KLK15 | c.482-2A>T p.X161_splice | Splice Site (SNP) | VAF 69/344 reads (20%) | catalogued as COSV56826922; called by muse, mutect2, varscan2
- L3MBTL4 | c.1742C>G p.T581R | Missense Mutation (SNP) | VAF 164/534 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV53122869; called by muse, mutect2, varscan2
- L3MBTL4 | c.385A>T p.T129S | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV53122879; called by muse, varscan2
- L3MBTL4 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 40/234 reads (17%) | catalogued as COSV53122890; called by muse, varscan2
- LBX1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64621796; called by muse, mutect2, varscan2
- LCA5 | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs1246123213, COSV63971378; called by muse, mutect2, varscan2
- LILRB3 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs1555885785; called by muse, mutect2, varscan2
- LIPK | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV68201079, COSV68201147; called by muse, mutect2, varscan2
- LRIF1 | c.1269G>C p.Q423H | Missense Mutation (SNP) | VAF 107/583 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV63897366; called by muse, mutect2, varscan2
- LRP1 | c.9622G>A p.A3208T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54511423; called by mutect2, varscan2
- LRP2 | c.7714C>G p.L2572V | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as COSV55553558, COSV99789711; called by muse, mutect2, varscan2
- LRP2 | c.5934A>T p.E1978D | Missense Mutation (SNP) | VAF 71/382 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.139); catalogued as COSV55553570; called by muse, mutect2, varscan2
- MGA | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV54953906; called by mutect2, varscan2
- MPP2 | c.1558G>A p.A520T (on ENST00000461854 / NM_001278372.2; = p.A496T on NM_005374.5) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV52235894; called by muse, mutect2, varscan2
- MTERF2 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV53527582; called by muse, mutect2, varscan2
- MTNR1B | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.181); catalogued as rs1432068053, COSV57066581; called by muse, mutect2, varscan2
- MUC16 | c.43282A>G p.R14428G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66690355; called by muse, mutect2, varscan2
- MVB12A | c.668A>C p.H223P | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57678895; called by muse, mutect2
- MX2 | c.252G>T p.G84= | Splice Region (SNP) | VAF 29/67 reads (43%) | catalogued as COSV58096545; called by muse, mutect2, varscan2
- MYH2 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55431878; called by muse, mutect2, varscan2
- MYH6 | c.4837G>T p.V1613F | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV62450530, COSV62453549; called by muse, mutect2, varscan2
- MYO5A | c.2477G>C p.R826P | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62560284; called by muse, mutect2, varscan2
- MYOG | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.187); catalogued as COSV54095548; called by muse, mutect2, varscan2
- N4BP1 | c.1734G>C p.R578S | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV52210867; called by muse, mutect2, varscan2
- NLRX1 | c.2663dup p.A889Cfs*3 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | catalogued as rs751657075; called by pindel, varscan2
- NOL9 | c.1400G>C p.R467P | Missense Mutation (SNP) | VAF 76/492 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66625966, COSV66625991; called by muse, mutect2, varscan2
- NOVA1 | c.227A>T p.Q76L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV57477131; called by muse, mutect2, varscan2
- NPY5R | c.463C>G p.H155D | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV58452016; called by muse, mutect2, varscan2
- NRXN2 | c.2960T>A p.L987* | Nonsense Mutation (SNP) | VAF 26/263 reads (10%) | catalogued as COSV55453427; called by muse, mutect2
- NSD1 | c.4642-1G>C p.X1548_splice | Splice Site (SNP) | VAF 18/114 reads (16%) | catalogued as COSV61776444; called by muse, mutect2, varscan2
- OLFM4 | c.203A>T p.Q68L | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV54577426; called by muse, mutect2, varscan2
- OR1A2 | c.729C>G p.H243Q | Missense Mutation (SNP) | VAF 104/424 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67936434; called by muse, mutect2, varscan2
- OR4L1 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.264); catalogued as rs191943707, COSV59849785; called by muse, mutect2, varscan2
- OR4M1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 204/436 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60061404; called by muse, mutect2, varscan2
- OR4P4 | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58922011; called by muse, mutect2, varscan2
- OR5D14 | c.194T>A p.L65H | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765200908, COSV59456354; called by muse, mutect2, varscan2
- OR5F1 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546474; called by muse, mutect2, varscan2
- OR5M10 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV73242321; called by muse, mutect2, varscan2
- OR9I1 | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.329); catalogued as COSV56926053; called by muse, mutect2, varscan2
- OR9Q1 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59040464; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1669G>T p.G557W (on ENST00000259318 / NM_001136562.3; = p.G788W on NM_007203.5) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV52176395; called by muse, mutect2, varscan2
- PAX8 | c.920T>C p.I307T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs760553635, COSV54508704; called by muse, mutect2, varscan2
- PBX1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63343698; called by muse, mutect2, varscan2
- PCNX1 | c.5664C>A p.N1888K | Missense Mutation (SNP) | VAF 143/457 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV53094905; called by muse, mutect2, varscan2
- PDE11A | c.2110C>T p.H704Y | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53695075; called by muse, mutect2
- PDYN | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472967766, COSV54101788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZRN4 | c.1373G>T p.G458V (on ENST00000402685 / NM_001164595.2; = p.G200V on NM_013377.4) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54198138, COSV54213978; called by muse, mutect2, varscan2
- PEG10 | c.524G>C p.R175P (on ENST00000482108 / NM_001040152.2; = p.R209P on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV71788246, COSV71788437; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 22/170 reads (13%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3CA | c.3134A>T p.D1045V | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV55928381, COSV99834205; called by muse, mutect2, varscan2
- PLCB3 | c.1745G>T p.S582I | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.807); catalogued as COSV54188585; called by muse, mutect2, varscan2
- PLCL1 | c.2068G>T p.G690* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | catalogued as COSV70822872, COSV70832552; called by muse, mutect2
- PLCZ1 | c.969A>T p.E323D | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.369); catalogued as COSV56852691; called by muse, mutect2, varscan2
- PLEKHH2 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.698); catalogued as COSV56753763, COSV99174357; called by muse, mutect2, varscan2
- PLXNA4 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV58126494; called by muse, mutect2, varscan2
- PPP3CA | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59923678; called by muse, mutect2, varscan2
- PRAMEF2 | c.1168T>C p.S390P | Missense Mutation (SNP) | VAF 98/360 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV53575467; called by muse, mutect2, varscan2
- PSG8 | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs759960457; called by mutect2, varscan2
- PSMC5 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV56739314; called by muse, mutect2, varscan2
- PTPRC | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as rs1456885006, COSV61409834; called by muse, mutect2, varscan2
- PTPRM | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 43/199 reads (22%) | catalogued as COSV59859458; called by muse, mutect2, varscan2
- PUM2 | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57580731; called by muse, mutect2, varscan2
- RASAL1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV55656077; called by muse, mutect2, varscan2
- RECQL5 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV58647413; called by muse, mutect2
- REG1A | c.434-1G>C p.X145_splice | Splice Site (SNP) | VAF 29/90 reads (32%) | catalogued as COSV52069812; called by muse, mutect2, varscan2
- RELN | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 114/341 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.444); catalogued as COSV59002630; called by muse, mutect2, varscan2
- RGS1 | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV66505370; called by muse, mutect2, varscan2
- RGS6 | c.21T>A p.D7E | Missense Mutation (SNP) | VAF 161/344 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.164); catalogued as COSV59577119; called by muse, mutect2, varscan2
- RHNO1 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.103); catalogued as rs765570307; called by muse, mutect2, varscan2
- RPL8 | c.769A>G p.N257D | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV52799253; called by muse, mutect2, varscan2
- RRM2B | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.145); catalogued as COSV52566826; called by muse, mutect2, varscan2
- RYR3 | c.859del p.R287Gfs*11 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | catalogued as COSV66798738; called by mutect2, pindel, varscan2
- RYR3 | c.3260G>T p.W1087L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66789708; called by muse, mutect2, varscan2
- SAMD13 | c.125A>G p.N42S (on ENST00000370671; = p.N36S on NM_001010971.3) | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as COSV65745008; called by muse, mutect2, varscan2
- SARS1 | c.1335G>C p.Q445H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52320836; called by muse, mutect2, varscan2
- SATB2 | c.1757A>T p.Q586L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV53483861; called by muse, mutect2
- SCN7A | c.1455G>C p.W485C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69271599; called by muse, mutect2, varscan2
- SEPTIN14 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 91/476 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66425881, COSV66427777; called by muse, mutect2, varscan2
- SERPINA11 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 227/482 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1566783837, COSV58241934; called by muse, mutect2, varscan2
- SGIP1 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV52769077; called by muse, mutect2, varscan2
- SGO2 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV63415460; called by muse, mutect2
- SHD | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 92/187 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV73378720; called by muse, mutect2, varscan2
- SLC17A1 | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 92/538 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV55078993; called by mutect2, varscan2
- SLC17A7 | c.561C>G p.Y187* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV55547763; called by muse, mutect2, varscan2
- SLC39A10 | c.743C>G p.T248R | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV62767427; called by muse, mutect2, varscan2
- SMOX | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV53864954; called by muse, mutect2
- SNX11 | c.327-1G>T p.X109_splice | Splice Site (SNP) | VAF 72/371 reads (19%) | catalogued as COSV63658520; called by muse, mutect2, varscan2
- SPAM1 | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV56143916; called by muse, mutect2, varscan2
- SPATA4 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV54590014, COSV54591284; called by muse, mutect2, varscan2
- SPOCK3 | c.1142-1G>T p.X381_splice | Splice Site (SNP) | VAF 17/87 reads (20%) | catalogued as COSV100693246; called by muse, mutect2, varscan2
- SRGAP3 | c.2548dup p.V850Gfs*10 | Frame Shift Ins (INS) | VAF 12/105 reads (11%) | catalogued as rs759698239; called by mutect2, varscan2
- SRP72 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs149517121, COSV61377041; called by muse, mutect2, varscan2
- SSUH2 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV58030363; called by muse, mutect2, varscan2
- ST18 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.789); catalogued as COSV52494420; called by mutect2, varscan2
- STK16 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50278254; called by muse, mutect2, varscan2
- STK32B | c.107A>T p.K36M | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51487733; called by muse, mutect2, varscan2
- SUZ12 | c.803del p.G268Efs*32 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as COSV100496901; called by mutect2, pindel, varscan2
- SYK | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778118969, COSV65324890; called by muse, mutect2, varscan2
- SYNE1 | c.18207G>T p.E6069D (on ENST00000367255 / NM_182961.4; = p.E5998D on NM_033071.3) | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV54931159; called by muse, mutect2
- SYNE1 | c.12775G>A p.E4259K (on ENST00000367255 / NM_182961.4; = p.E4188K on NM_033071.3) | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV54984117; called by muse, mutect2, varscan2
- TAT | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63532879; called by muse, mutect2, varscan2
- TBX22 | c.1136A>G p.N379S | Missense Mutation (SNP) | VAF 127/207 reads (61%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV64786023; called by muse, mutect2, varscan2
- TEKT3 | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 254/692 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV58627646; called by muse, mutect2, varscan2
- TENM3 | c.141G>T p.L47F | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV69308425; called by muse, mutect2, varscan2
- TERF1 | c.1273A>G p.R425G (on ENST00000276603 / NM_017489.3; = p.R405G on NM_003218.4) | Missense Mutation (SNP) | VAF 52/493 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52577897; called by muse, mutect2, varscan2
- THUMPD1 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV67263214; called by muse, mutect2, varscan2
- TIE1 | c.1405G>C p.V469L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.206); catalogued as rs1252453725, COSV65249744; called by muse, mutect2, varscan2
- TJAP1 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52500953; called by muse, mutect2, varscan2
- TMCO5A | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60464781; called by muse, mutect2, varscan2
- TMEM177 | c.392G>T p.W131L | Missense Mutation (SNP) | VAF 51/506 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV55608749; called by muse, mutect2
- TMEM182 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101305438, COSV68424820; called by muse, mutect2, varscan2
- TMEM216 | c.317A>T p.Y106F (on ENST00000515837 / NM_001173990.3; = p.Y45F on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.075); catalogued as COSV58426193; called by muse, mutect2, varscan2
- TMEM45A | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 85/625 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs769958679, COSV60255496; called by muse, mutect2, varscan2
- TRAM1L1 | c.576C>A p.D192E | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.162); catalogued as COSV60291950; called by muse, mutect2, varscan2
- TRIM58 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV63570260; called by muse, mutect2, varscan2
- TRPA1 | c.1392G>T p.R464S | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV51561884; called by muse, mutect2, varscan2
- TRPM7 | c.5248G>C p.A1750P | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57916479; called by muse, mutect2, varscan2
- TSPEAR | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV59962604; called by muse, varscan2
- TTLL7 | c.762C>A p.N254K | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53084476; called by muse, mutect2, varscan2
- TTLL9 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV60592537; called by muse, mutect2, varscan2
- TTN | c.72395C>T p.A24132V (on ENST00000591111; = p.A16708V on NM_003319.4) | Missense Mutation (SNP) | VAF 54/128 reads (42%) | PolyPhen probably damaging (0.995); catalogued as COSV60067260; called by muse, mutect2, varscan2
- TTPA | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99478606; called by muse, mutect2
- UBA2 | c.1118G>C p.R373T | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs1255024074, COSV55828422; called by muse, mutect2, varscan2
- UGT1A10 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 241/940 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV60839255; called by muse, mutect2, varscan2
- URI1 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1374135298, COSV56349989; called by muse, mutect2, varscan2
- USH2A | c.12595G>C p.A4199P | Missense Mutation (SNP) | VAF 59/358 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV56370596; called by muse, mutect2, varscan2
- USP16 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV57625413; called by muse, mutect2, varscan2
- WDR17 | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54574280; called by muse, mutect2, varscan2
- WDR35 | c.628A>C p.I210L | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV55602804; called by muse, mutect2, varscan2
- WDR72 | c.1855A>T p.I619F | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64746920; called by muse, varscan2
- XPO4 | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55007438; called by muse, mutect2, varscan2
- ZDBF2 | c.807G>T p.L269F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV65626041; called by muse, mutect2, varscan2
- ZIC1 | c.941C>G p.A314G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV51552824, COSV51553658; called by mutect2, varscan2
- ZIM2 | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV55633968; called by muse, mutect2, varscan2
- ZMYM1 | c.2869A>T p.T957S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV63251926; called by muse, mutect2, varscan2
- ZNF292 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.212); catalogued as COSV60539502; called by muse, mutect2, varscan2
- ZNF32 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV65641654; called by muse, mutect2, varscan2
- ZNF417 | c.936T>G p.I312M | Missense Mutation (SNP) | VAF 120/484 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV56308360; called by muse, mutect2, varscan2
- ZNF521 | c.3433G>T p.V1145F | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64124244, COSV64127046; called by muse, mutect2, varscan2
- ZNF665 | c.451A>T p.T151S (on ENST00000600412; = p.T216S on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.026); catalogued as COSV67215133; called by muse, mutect2, varscan2
- ZNF91 | c.2410G>T p.G804C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56084735; called by muse, mutect2, varscan2
- ZNF99 | c.1534G>C p.E512Q | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV68055761; called by muse, mutect2, varscan2
- ABCB11 | c.2074A>T p.R692W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CFTR | c.2570dup p.S858Efs*38 | Frame Shift Ins (INS) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- CNDP2 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2
- DNAH10 | c.2991G>A p.M997I (on ENST00000409039; = p.M936I on NM_207437.3) | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- DSCAML1 | c.4912C>A p.P1638T (on ENST00000321322; = p.P1578T on NM_020693.4) | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA6 | c.2258C>A p.P753Q (on ENST00000389672 / NM_001080448.3; = p.P145Q on NM_173655.4) | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- FLNA | c.2245dup p.W749Lfs*73 | Frame Shift Ins (INS) | VAF 71/141 reads (50%) | called by mutect2, pindel, varscan2
- GUCY2C | c.1548dup p.D517Rfs*6 | Frame Shift Ins (INS) | VAF 26/156 reads (17%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.308T>A p.M103K | Missense Mutation (SNP) | VAF 184/444 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- KAT8 | c.1344dup p.K449Qfs*39 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- KIR3DL2 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 132/1526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIR3DL2 | c.1000+1G>T p.X334_splice | Splice Site (SNP) | VAF 130/1510 reads (9%) | called by muse, varscan2
- LCA5 | c.1924G>T p.G642W | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LDHAL6B | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRP6 | c.2413del p.L805Ffs*10 | Frame Shift Del (DEL) | VAF 36/185 reads (19%) | called by mutect2, pindel, varscan2
- MAEL | c.155A>C p.E52A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.228); called by muse, mutect2
- PIK3CG | c.1100del p.G367Afs*17 | Frame Shift Del (DEL) | VAF 24/222 reads (11%) | called by mutect2, pindel, varscan2
- PRSS23 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RANBP3 | c.1004dup p.L337Ifs*20 (on ENST00000340578 / NM_007322.3; = p.L332Ifs*20 on NM_003624.3) | Frame Shift Ins (INS) | VAF 4/33 reads (12%) | called by pindel, varscan2
- RGL3 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.219); called by muse, mutect2
- SDC3 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A3 | c.3545C>A p.P1182Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- TMEM161B | c.463T>A p.L155I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TTN | c.9168del p.H3057Ifs*2 (on ENST00000591111; = p.H3011Ifs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel, varscan2
- VPS26B | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZNF175 | c.333T>G p.I111M | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- ZZEF1 | c.7612G>T p.D2538Y | Missense Mutation (SNP) | VAF 31/666 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AC100868.1 | c.1131C>A p.S377= | Silent (SNP) | VAF 37/316 reads (12%) | catalogued as COSV51842945; called by muse, mutect2, varscan2
- ACTN2 | c.2262G>A p.Q754= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as COSV100856486, COSV63975016; called by muse, mutect2, varscan2
- AGBL1 | c.2985C>G p.G995= | Silent (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- AHCYL1 | c.594C>T p.F198= | Silent (SNP) | VAF 85/185 reads (46%) | catalogued as rs144479834; called by muse, mutect2, varscan2
- ANKS6 | c.1437G>T p.L479= | Silent (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- AQR | c.1737G>T p.R579= | Silent (SNP) | VAF 66/270 reads (24%) | catalogued as COSV50034683; called by muse, mutect2, varscan2
- BEST3 | c.822C>A p.P274= | Silent (SNP) | VAF 119/972 reads (12%) | called by muse, mutect2, varscan2
- C10orf90 | c.1860C>A p.T620= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as COSV52955502; called by muse, mutect2, varscan2
- CD300LF | c.219G>A p.Q73= | Silent (SNP) | VAF 164/868 reads (19%) | catalogued as COSV56897077; called by muse, mutect2, varscan2
- CHD7 | c.4521C>T p.S1507= | Silent (SNP) | VAF 30/372 reads (8%) | catalogued as COSV71110585; called by muse, mutect2
- CRACD | c.234C>A p.P78= | Silent (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- CRB1 | c.1734G>T p.V578= | Silent (SNP) | VAF 47/345 reads (14%) | catalogued as COSV66330434; called by muse, mutect2, varscan2
- CSMD2 | c.525C>T p.A175= | Silent (SNP) | VAF 164/759 reads (22%) | catalogued as rs774840689, COSV53912990, COSV99589479; called by muse, mutect2, varscan2
- CTNNA2 | c.180A>G p.L60= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as COSV63568107; called by muse, mutect2, varscan2
- CYP2C19 | c.96C>A p.G32= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs758671110, COSV64907768; called by muse, mutect2, varscan2
- DENND2D | c.783G>T p.A261= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- DNAH3 | c.7732C>A p.R2578= | Silent (SNP) | VAF 127/191 reads (66%) | catalogued as COSV54522013; called by muse, mutect2, varscan2
- ELN | c.753C>A p.G251= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV52710319; called by muse, mutect2
- ENPP2 | c.2568G>A p.L856= (on ENST00000075322 / NM_001040092.3; = p.L908= on NM_006209.5) | Silent (SNP) | VAF 103/487 reads (21%) | catalogued as COSV50014954; called by muse, mutect2, varscan2
- FLG | c.4524A>C p.S1508= | Silent (SNP) | VAF 68/158 reads (43%) | catalogued as rs760272161, COSV64241935; called by muse, mutect2, varscan2
- FLG2 | c.4761G>A p.G1587= | Silent (SNP) | VAF 125/655 reads (19%) | catalogued as COSV66168734; called by muse, mutect2, varscan2
- GALR1 | c.1047G>A p.V349= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs748559973, COSV55317095; called by muse, mutect2, varscan2
- GRM3 | c.2478C>T p.I826= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as rs999736107, COSV64471907; called by muse, mutect2, varscan2
- GUCY2C | c.24G>A p.L8= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as COSV53790252; called by muse, mutect2, varscan2
- H3-5 | c.264C>A p.A88= | Silent (SNP) | VAF 34/175 reads (19%) | called by muse, mutect2, varscan2
- HIVEP3 | c.2409C>T p.T803= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs567246160, COSV56015616; called by muse, mutect2, varscan2
- IGKV1D-8 | c.240C>T p.V80= | Silent (SNP) | VAF 173/390 reads (44%) | catalogued as rs778247637; called by muse, mutect2, varscan2
- KDM4B | c.1950C>T p.D650= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs146435915; called by muse, mutect2, varscan2
- KLHL1 | c.1056C>A p.L352= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV64772638; called by muse, mutect2, varscan2
- KNTC1 | c.2469G>T p.L823= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV61080253; called by muse, mutect2
- LAMA1 | c.5265A>T p.S1755= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as COSV67537112; called by muse, mutect2, varscan2
- LIPG | c.69A>C p.V23= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV54296309; called by muse, mutect2, varscan2
- LRRC43 | c.240G>T p.T80= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV60289996; called by muse, mutect2, varscan2
- MAGEA6 | c.411G>T p.G137= | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as COSV61448992; called by muse, mutect2, varscan2
- MAGEB6 | c.807C>T p.G269= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV66872288; called by muse, mutect2, varscan2
- MAP3K5 | c.2736G>A p.K912= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV62889197; called by muse, mutect2
- MAP6 | c.1956C>A p.A652= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV59075800; called by muse, mutect2, varscan2
- MS4A12 | c.369C>A p.A123= | Silent (SNP) | VAF 33/183 reads (18%) | catalogued as COSV50014495; called by muse, mutect2, varscan2
- NSUN2 | c.667C>T p.L223= | Silent (SNP) | VAF 333/543 reads (61%) | catalogued as rs757734986, COSV52954477; called by muse, mutect2, varscan2
- OR2W3 | c.645G>C p.L215= | Silent (SNP) | VAF 53/273 reads (19%) | catalogued as COSV64456897; called by muse, mutect2, varscan2
- OR4P4 | c.666C>A p.T222= | Silent (SNP) | VAF 58/171 reads (34%) | catalogued as COSV58922022; called by muse, mutect2, varscan2
- PAQR3 | c.486C>T p.Y162= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs751898477; called by muse, mutect2, varscan2
- PMP2 | c.33T>A p.L11= | Silent (SNP) | VAF 37/269 reads (14%) | catalogued as COSV56267088; called by muse, mutect2, varscan2
- PPP1R3A | c.3348A>G p.K1116= | Silent (SNP) | VAF 92/340 reads (27%) | catalogued as COSV52882717; called by muse, mutect2, varscan2
- PRDM9 | c.2244T>C p.Y748= | Silent (SNP) | VAF 91/564 reads (16%) | catalogued as rs751238865, COSV57006428; called by muse, varscan2
- PRKCG | c.2046C>T p.H682= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV54727866; called by mutect2, varscan2
- PTPRJ | c.3706C>T p.L1236= | Silent (SNP) | VAF 19/236 reads (8%) | called by muse, mutect2
- RALYL | c.63C>A p.S21= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV72820920; called by muse, mutect2, varscan2
- RNASET2 | c.450G>A p.V150= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs747165370, COSV50351551; called by muse, mutect2, varscan2
- RNF111 | c.2488T>C p.L830= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV62086066; called by muse, mutect2, varscan2
- ROS1 | c.2208C>A p.I736= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV63855295, COSV63857031; called by muse, mutect2, varscan2
- RYR1 | c.2064C>T p.T688= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as rs764993324, COSV62087193, COSV62097525; called by muse, mutect2, varscan2
- SASH1 | c.2412G>T p.V804= | Silent (SNP) | VAF 11/194 reads (6%) | called by muse, mutect2
- SGO2 | c.1263A>C p.S421= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV100764846, COSV63414500, COSV63415452; called by muse, mutect2
- SGO2 | c.1317G>T p.L439= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV63415466; called by muse, mutect2, varscan2
- SHISAL2A | c.471C>T p.L157= | Silent (SNP) | VAF 126/531 reads (24%) | catalogued as COSV68979789; called by muse, mutect2, varscan2
- SLC12A1 | c.3195A>T p.I1065= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as COSV66794910; called by muse, mutect2, varscan2
- SLC26A7 | c.903G>C p.P301= | Silent (SNP) | VAF 42/418 reads (10%) | catalogued as COSV52593554, COSV99404524; called by muse, mutect2, varscan2
- SLC3A2 | c.1575G>A p.R525= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs1172445420, COSV100101148, COSV58603525; called by muse, mutect2, varscan2
- SLCO6A1 | c.1806C>A p.A602= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV65809861; called by muse, mutect2, varscan2
- SNRPN | c.642C>A p.G214= | Silent (SNP) | VAF 29/201 reads (14%) | catalogued as COSV57596593, COSV57597124; called by muse, mutect2, varscan2
- STAB2 | c.3513C>T p.A1171= | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as COSV66339076; called by muse, mutect2, varscan2
- SYT1 | c.789G>T p.L263= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as COSV54048289; called by muse, mutect2, varscan2
- TBX20 | c.1257G>A p.P419= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1472539296, COSV68783634; called by muse, mutect2, varscan2
- TMEM132D | c.321C>A p.P107= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV70605042; called by muse, mutect2, varscan2
- TNFRSF8 | c.873A>G p.T291= | Silent (SNP) | VAF 26/175 reads (15%) | catalogued as COSV55796574; called by muse, mutect2, varscan2
- TSPY1 | c.573A>G p.E191= | Silent (SNP) | VAF 38/696 reads (5%) | catalogued as COSV70474909; called by muse, mutect2
- TTC21B | c.2016G>T p.R672= | Silent (SNP) | VAF 46/344 reads (13%) | catalogued as COSV54630704; called by muse, mutect2, varscan2
- TTN | c.37161G>C p.L12387= (on ENST00000591111; = p.L4963= on NM_003319.4) | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV60067299; called by muse, mutect2, varscan2
- USH2A | c.14874C>T p.N4958= | Silent (SNP) | VAF 33/139 reads (24%) | catalogued as rs749286172, COSV56370578; called by muse, mutect2, varscan2
- USP28 | c.2025G>T p.V675= | Silent (SNP) | VAF 100/977 reads (10%) | catalogued as COSV50162966; called by muse, varscan2
- VPS13D | c.8676G>C p.L2892= | Silent (SNP) | VAF 56/204 reads (27%) | catalogued as COSV50639498; called by muse, mutect2
- WDR17 | c.174C>A p.T58= | Silent (SNP) | VAF 48/174 reads (28%) | catalogued as COSV54574292; called by muse, mutect2, varscan2
- ZFHX4 | c.8766A>G p.K2922= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV50809410; called by muse, mutect2, varscan2
- ZNF426 | c.1581A>G p.T527= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV53469245; called by muse, mutect2, varscan2
- MACF1 | c.15832-9404C>G | Intron (SNP) | VAF 6/19 reads (32%) | catalogued as COSV57121400; called by muse, mutect2, varscan2
- NFASC | c.2471-1415G>A | Intron (SNP) | VAF 14/80 reads (18%) | catalogued as rs138795461; called by muse, mutect2
- XIST | n.9043C>A | RNA (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- ZNF544 | c.244+4579G>T | Intron (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
